Gene-level copy-number profile of tumor specimen HCM-WCMC-0502-C15-01A from HCMI case HCM-WCMC-0502-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 42.9 years (15,658 days).
Specimen HCM-WCMC-0502-C15-01A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file fe08bebb-d12a-4e7b-a8ae-ccae72781bdf.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-WCMC-0502-C15-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,732 have no estimate.
https://portal.gdc.cancer.gov/files/8d00671c-5b46-437c-8347-2883a5bb4ba8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 814; copy number 1: 10,995; copy number 2: 41,737; copy number 3: 5,020; copy number 4: 237; copy number 5: 8; copy number 6: 3; copy number 7: 1; copy number 8: 26; copy number 9: 16; copy number 12: 2; copy number 13: 1; copy number 14: 2; copy number 22: 29.

Homozygous deletions (total copy number 0; autosomes only): 292 genes in 28 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,232,237–1,292,029, 6 genes: B3GALT6, C1QTNF12, AL162741.1, UBE2J2, LINC01786, SCNN1D.
- chr1:1,296,110–1,296,170, 1 gene (within-gene range 0–2): MIR6726.
- chr1:16,740,516–16,770,237, 2 genes (within-gene range 0–1): RNU1-4, MST1L.
- chr1:143,699,456–143,699,619, 1 gene: RNVU1-17.
- chr1:223,947,605–223,950,416, 1 gene: CICP5.
- chr4:49,486,926–49,589,529, 12 genes: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr4:187,970,273–188,109,603, 4 genes: AC108073.1, ZFP42, TRIML2, AC108073.2.
- chr5:21,196,720–21,341,375, 2 genes: AC140172.1, AC093274.1.
- chr5:74,084,068–74,103,216, 1 gene: LINC02122.
- chr5:180,967,189–180,970,762, 2 genes: AC091874.2, AC091874.1.
- chr7:151,464,650–151,464,938, 1 gene: RN7SL76P.
- chr8:1,730,206–7,143,841, 78 genes (broad region; genes not listed).
- chr8:23,243,637–25,141,968, 34 genes: CHMP7, R3HCC1, LOXL2, AC090197.1, ENTPD4, AC104561.1, AC104561.2, AC104561.4, AC104561.3, SLC25A37, RNU4-71P, SINHCAFP3, NKX3-1, NKX2-6, AC012574.1, AC012574.2, AC012119.2, AC012119.1, STC1, RNU1-148P, AC023202.1, ADAM28, AC120193.1, ADAMDEC1, ADAM7, AC024958.1, AF106564.1, NEFM, NEFL, MIR6841, AC107373.2, AC107373.1, AC107373.3, AC073581.1.
- chr11:1,554,051–1,572,271, 1 gene (within-gene range 0–2): DUSP8.
- chr11:22,283,730–22,338,245, 1 gene (within-gene range 0–2): AC104009.1.
- chr11:62,908,679–62,921,807, 2 genes: CHRM1, AP000438.1.
- chr12:13,371,089–13,387,167, 1 gene: LINC01559.
- chr12:56,380,361–56,414,045, 3 genes: AC025574.1, AC024884.2, AC024884.1.
- chr14:18,343,038–18,419,273, 3 genes: RNU6-458P, CR383658.2, BNIP3P6.
- chr15:25,172,635–25,204,438, 18 genes (within-gene range 0–1): SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19.
- chr16:981,770–1,280,544, 22 genes: SOX8, AC009041.1, SSTR5-AS1, AC009041.2, SSTR5, C1QTNF8, AL031713.1, AL031598.1, AC120498.8, CACNA1H, AC120498.3, AC120498.1, AC120498.6, TPSG1, AC120498.10, TPSB2, TPSAB1, TPSD1, AC120498.2, PRSS29P, AC120498.7, AC120498.5.
- chr16:1,493,344–1,510,457, 1 gene (within-gene range 0–1): TELO2.
- chr16:1,512,979–1,555,580, 3 genes (within-gene range 0–1): AL031705.1, TMEM204, AL031719.1.
- chr17:8,310,241–8,383,187, 8 genes (within-gene range 0–2): ARHGEF15, AC135178.2, AC135178.1, AC135178.5, ODF4, KRBA2, AC135178.4, AC135178.3.
- chr17:45,435,900–45,490,749, 3 genes (within-gene range 0–2): PLEKHM1, AC091132.2, MIR4315-1.
- chr17:45,585,871–45,608,918, 5 genes: DND1P1, AC126544.2, AC126544.1, MAPK8IP1P2, RPS26P8.
- chr22:15,282,557–17,022,570, 75 genes (within-gene range 0–1) (broad region; genes not listed).
- chr22:41,981,304–41,982,217, 1 gene (within-gene range 0–2): Z99716.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 88 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,498,785–143,500,512, 2 genes, copy number 6: AC239859.2, LINC02799.
- chr2:89,319,625–89,600,680, 3 genes, copy number 5: IGKV1-39, IGKV2-40, 5S_rRNA.
- chr3:90,261,414–93,843,862, 2 genes, copy number 5: HSPE1P19, RNU6-488P.
- chr8:7,190,901–7,191,563, 1 gene, copy number 7: RPS3AP33.
- chr9:40,883,634–40,883,763, 1 gene, copy number 6: AL353626.2.
- chr12:24,212,421–27,695,564, 71 genes, copy number 8–22 (broad region; genes not listed).
- chr15:28,506,625–28,561,379, 2 genes, copy number 9–13: ABCB10P4, AC138749.1.
- chr18:9,102,630–9,134,345, 1 gene, copy number 5 (within-gene range 2–5): NDUFV2.
- chr18:9,112,404–9,136,645, 2 genes, copy number 5 (within-gene range 2–5): AP005899.1, NDUFV2-AS1.
- chr21:43,446,601–43,479,534, 3 genes, copy number 8–12: LINC00319, LINC00313, AP001048.1.

Autosomal genes at a single copy (total copy number 1): 8,696. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
